TCGA case TCGA-BJ-A0ZG — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3810f36-d2b4-4a45-ad08-a4dbfb9d27aa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 80.4 years (29,375 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 775 days (2.1 years).
   Pathology details: Consistent pathology review: Yes; Measurement unit: Centimeters; Tumor depth measurement: 1.2; Tumor length measurement: 3.7; Tumor width measurement: 2.7.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 230 days; Disease response: Tumor Free.
- Days to follow up: 775 days (2.1 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Molecular and laboratory tests
- BRAF substitution: Positive; Amino-acid change: V600E.
- RAS, NOS mutation, nos: Negative.
- RET translocation: Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Nodular Hyperplasia.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BJ-A0ZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-BJ-A0ZG-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BJ-A0ZG-01A-01-BSA: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BJ-A0ZG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BJ-A0ZG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Genotypic analysis detected: Yes; BRAF mutation result: p. V600E, c.1799T >A; Ras mutation result: not identified.
- Patient personal medical history thyroid gland disorder names: History thyroid disease: Nodular Hyperplasia.
- Genotyping results gene mutation not reported reasons: Reasons for Genotypic Analysis not Detected: No RAS Mutation Detected; Reasons for Genotypic Analysis not Detected: No RET/PTC Rearrangement Detected.
- Follow-up form 1: Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: Tumor free.
- Follow-up form 1, New tumor: New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 775 days; disease-specific survival: no event (censored), 775 days; progression-free interval: no event (censored), 775 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BJ-A0ZG-01A-11D-A10T-01): tumor purity 0.63, ploidy 2, whole-genome doublings 0.
